Somatic mutation profile of tumor specimen BA3321D (aliquot aq-BA3321D) from BEATAML1.0 case 2547, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.3 years (26,782 days).
Specimen BA3321D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9953c30c-920e-4d4f-b1d5-5e090f721dbd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3349D (Solid Tissue Normal), aliquot aq-BA3349D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0f83a2-2ee0-47e3-a4cf-78e0d3d3b185

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGA2 | c.1828A>C p.K610Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs1349721639; called by muse, mutect2, varscan2
